Somatic mutation profile of tumor specimen TCGA-FS-A4F8-06A (aliquot TCGA-FS-A4F8-06A-11D-A25O-08) from TCGA case TCGA-FS-A4F8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.8 years (24,023 days).
Specimen TCGA-FS-A4F8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f61f8143-bb8b-4697-a3ff-55b483379293.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A4F8-10B (Blood Derived Normal), aliquot TCGA-FS-A4F8-10B-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d55fb8d-ad30-4365-8660-d0626f5654c0

The open-access MAF lists 197 somatic variants for this specimen: 135 protein-altering or splice-affecting, 60 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 60, Splice Region 5, Nonsense Mutation 3, 5'Flank 1, Frame Shift Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALX3 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121908168, CM092883, COSV100873890; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- INMT | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 12/64 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs759141767, COSV50000201; called by muse, mutect2
- MAP2K2 | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.662); catalogued as rs1057519809, COSV53562779; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TACC3 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV57603049; called by muse, mutect2, varscan2
- ACOT6 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.178); catalogued as COSV66968815, COSV66969054; called by muse, mutect2
- ACSM4 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV68066865; called by muse, mutect2, varscan2
- ADARB2 | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761776908, COSV67215893; called by muse, mutect2, varscan2
- ADGRV1 | c.6833G>A p.G2278E | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101316407, COSV67979265; called by muse, mutect2
- AGAP1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1288473351, COSV58318298; called by muse, mutect2, varscan2
- ANK3 | c.10876G>A p.E3626K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV55046019, COSV55063613; called by muse, mutect2, varscan2
- ANKFN1 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs368152107; called by muse, mutect2, varscan2
- ANKRD30A | c.3479G>A p.R1160K (on ENST00000611781; = p.R1104K on NM_052997.2) | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.056); catalogued as COSV64604862, COSV64613933; called by muse, mutect2, varscan2
- AOC1 | c.1231C>T p.H411Y | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.295); catalogued as COSV62867128; called by muse, mutect2, varscan2
- ARMC4 | c.2610G>A p.K870= | Splice Region (SNP) | VAF 4/26 reads (15%) | catalogued as COSV59472682, COSV59477138; called by muse, mutect2, varscan2
- ARRDC5 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV67787760; called by muse, mutect2, varscan2
- ASXL3 | c.5567G>A p.G1856E | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.235); catalogued as COSV52458476; called by muse, mutect2
- ATP2B3 | c.3530C>T p.P1177L | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.029); catalogued as COSV54841171, COSV54842211; called by muse, mutect2, varscan2
- BBS9 | c.815A>G p.K272R | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as COSV54157906; called by muse, mutect2, varscan2
- BCL2A1 | c.217C>A p.Q73K | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.433); catalogued as rs761533059, COSV51212911; called by muse, mutect2, varscan2
- BIN2 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.989); catalogued as COSV57203765; called by muse, mutect2, varscan2
- BRD7 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67158347; called by muse, mutect2, varscan2
- BTBD7 | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58283843; called by muse, mutect2
- C1orf105 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as COSV62958851; called by muse, mutect2, varscan2
- CADPS2 | c.3398T>G p.V1133G | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57351150; called by muse, mutect2
- CAPZA3 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868744411, COSV56849081, COSV56850605; called by muse, mutect2
- CCNB3 | c.3670C>T p.R1224C | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs782145357, COSV52070254; called by muse, mutect2, varscan2
- CD200R1 | c.917A>G p.N306S (on ENST00000471858 / NM_170780.3; = p.N329S on NM_138806.4) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); catalogued as COSV55599449; called by muse, mutect2
- CDC42BPG | c.2510G>A p.R837K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV61345779; called by muse, mutect2, varscan2
- CDCP1 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV56103964; called by muse, mutect2, varscan2
- CDH8 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54850886; called by muse, mutect2, varscan2
- CFAP47 | c.2504G>A p.S835N | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.535); catalogued as COSV52881259; called by muse, mutect2, varscan2
- CHURC1 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV63035986; called by muse, mutect2, varscan2
- CMYA5 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as COSV71404217; called by muse, mutect2, varscan2
- COL5A1 | c.2894C>G p.P965R | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376435205; called by muse, mutect2, varscan2
- CPS1 | c.3521G>A p.R1174Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs553145464, COSV51803201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA2 | c.1696T>C p.Y566H | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58188376; called by muse, mutect2, varscan2
- CYP3A7 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.712); catalogued as rs1340630761, COSV60480636, COSV60481116; called by muse, mutect2, varscan2
- DACH1 | c.1654C>T p.P552S (on ENST00000619232 / NM_001366712.1; = p.P500S on NM_080759.6) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.351); catalogued as COSV57490796; called by muse, mutect2, varscan2
- DIPK2B | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV65005053, COSV65005099; called by muse, mutect2
- DMBT1 | c.3518G>A p.G1173E (on ENST00000338354 / NM_001377530.1; = p.G674E on NM_004406.3) | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV57535949; called by muse, mutect2, varscan2
- DNAH7 | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs192646926; called by muse, mutect2, varscan2
- DOCK3 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1253633877, COSV56505546; called by muse, mutect2, varscan2
- EIF2B5 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV56603768, COSV56605109; called by muse, mutect2, varscan2
- EPC1 | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV53923443; called by muse, mutect2, varscan2
- ERC2 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs750451019, COSV55603699; called by muse, mutect2, varscan2
- FAT4 | c.6445G>A p.D2149N | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58673294; called by muse, mutect2, varscan2
- FLG | c.6715C>T p.R2239W | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs767399613, COSV64237417; called by muse, mutect2, varscan2
- FLT1 | c.2360C>T p.S787F | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV56719116; called by muse, mutect2
- GPR139 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.497); catalogued as COSV58501799; called by muse, mutect2, varscan2
- GRK5 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1211407043, COSV64865685; called by muse, mutect2, varscan2
- HASPIN | c.2086G>A p.D696N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV53989893; called by muse, mutect2, varscan2
- HDC | c.204G>A p.G68= | Splice Region (SNP) | VAF 12/130 reads (9%) | catalogued as rs1306653916, COSV51085558; called by muse, mutect2
- HNF4G | c.1184C>T p.S395L (on ENST00000354370 / NM_001330561.2; = p.S442L on NM_004133.5) | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV62966073; called by muse, mutect2, varscan2
- IFT43 | c.213G>A p.S71= | Splice Region (SNP) | VAF 17/113 reads (15%) | catalogued as rs1172328141, COSV53137890; called by muse, mutect2, varscan2
- IGSF21 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV52126316; called by muse, mutect2, varscan2
- IL18RAP | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs752348672, COSV51824160; called by muse, mutect2, varscan2
- ITCH | c.1481C>T p.P494L (on ENST00000262650 / NM_001257137.3; = p.P453L on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.237); catalogued as COSV52929687; called by muse, mutect2, varscan2
- KRT25 | c.1214G>A p.G405E | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV56443833; called by muse, mutect2
- KRTAP24-1 | c.212G>T p.C71F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as COSV61089082; called by muse, mutect2, varscan2
- KRTCAP3 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as rs201542495, COSV51993238; called by muse, mutect2
- LDB3 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as COSV53938456; called by muse, mutect2, varscan2
- LRRC31 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1439194610, COSV52979718; called by muse, mutect2, varscan2
- MAGEB4 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66775264, COSV66776807; called by muse, mutect2, varscan2
- MAP3K1 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765046318, COSV68121985; called by muse, mutect2, varscan2
- MED24 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62417383; called by muse, mutect2, varscan2
- MEOX2 | c.704T>G p.F235C | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56287816; called by muse, mutect2, varscan2
- MESP2 | c.1004A>T p.Q335L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.666); catalogued as COSV59092098; called by muse, mutect2, varscan2
- MFSD12 | c.670G>T p.V224L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as COSV61534941; called by muse, mutect2
- MGAM | c.711G>A p.L237= | Splice Region (SNP) | VAF 7/56 reads (13%) | catalogued as COSV71886219; called by muse, mutect2, varscan2
- MMRN2 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV64400429; called by muse, mutect2
- MUC16 | c.17572G>A p.E5858K | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as COSV67447862, COSV67455077; called by muse, mutect2, varscan2
- MUC17 | c.3827G>A p.G1276E | Missense Mutation (SNP) | VAF 52/329 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.694); catalogued as COSV60281312; called by muse, mutect2, varscan2
- MYO1B | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs1559199927, COSV58427700; called by muse, mutect2
- N4BP1 | c.2233C>G p.Q745E | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV52209630; called by muse, mutect2
- NBEA | c.4663G>A p.D1555N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV59763119; called by muse, mutect2, varscan2
- OCA2 | c.1730G>T p.G577V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as COSV62339571; called by muse, mutect2, varscan2
- OR2AT4 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59406404, COSV59407107; called by muse, mutect2, varscan2
- OR51D1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV62913870, COSV62914369; called by muse, mutect2, varscan2
- OR52H1 | c.775T>A p.F259I (on ENST00000322653; = p.F265I on NM_001005289.1) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59504962; called by muse, mutect2, varscan2
- PACS2 | c.2551G>A p.V851I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV57650308; called by muse, mutect2
- PASD1 | c.2204G>A p.G735E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); catalogued as rs1385785276, COSV64854236; called by muse, mutect2, varscan2
- PCDHA12 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56480564; called by muse, mutect2, varscan2
- PCDHA6 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs542612445, COSV65349787; called by muse, mutect2
- PCNX1 | c.6488C>T p.S2163L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV53089988; called by muse, mutect2, varscan2
- PIK3CG | c.1793G>A p.W598* | Nonsense Mutation (SNP) | VAF 14/102 reads (14%) | catalogued as COSV63245881; called by muse, mutect2, varscan2
- PLCB2 | c.3233C>T p.S1078F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53031013; called by muse, mutect2, varscan2
- PLK4 | c.2423G>A p.G808D | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as rs201490018, COSV54636472; called by muse, mutect2, varscan2
- PPIL6 | c.483G>A p.E161= | Splice Region (SNP) | VAF 8/25 reads (32%) | catalogued as COSV70022816; called by muse, mutect2
- PPIL6 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV70021681; called by muse, mutect2
- PRSS16 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV57914922; called by muse, mutect2, varscan2
- PRSS22 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50721031; called by muse, mutect2
- PRSS36 | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV51635700; called by muse, mutect2
- PTPRD | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.281); catalogued as rs1354824749, COSV61928182; called by muse, mutect2, varscan2
- PYGL | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99368811; called by muse, mutect2
- RASGEF1C | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV63177819; called by muse, mutect2
- RECQL5 | c.2938G>A p.E980K | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs761941890, COSV58637870; called by muse, mutect2
- RELN | c.1690C>T p.L564F | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV58987528; called by muse, mutect2, varscan2
- RGS9 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV52223348; called by muse, mutect2
- RNF185 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.968); catalogued as rs61743577; called by muse, mutect2, varscan2
- ROCK2 | c.3445C>T p.P1149S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as COSV59953856, COSV59960355; called by muse, mutect2
- RP1 | c.4400C>T p.S1467F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV55109243, COSV55113760; called by muse, mutect2, varscan2
- SAMD9L | c.2389C>T p.P797S | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV59079875; called by muse, mutect2, varscan2
- SCNM1 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.995); catalogued as COSV54859591; called by muse, mutect2, varscan2
- SERPINB3 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.761); catalogued as COSV52189996; called by muse, mutect2, varscan2
- SFMBT2 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62805980; called by muse, mutect2, varscan2
- SMYD2 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV65290411; called by muse, mutect2, varscan2
- SRGAP3 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as rs748179281, COSV64530895; called by muse, mutect2
- ST6GALNAC4 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | PolyPhen benign (0.015); catalogued as COSV59129407; called by muse, varscan2
- SYT17 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as COSV62545225; called by muse, mutect2, varscan2
- SYTL2 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV60356274; called by muse, mutect2
- TACC2 | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV57747526; called by muse, mutect2
- TCF4 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV61891254; called by muse, mutect2, varscan2
- TDRD3 | c.1303T>C p.Y435H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV52153501; called by muse, mutect2, varscan2
- TMPRSS9 | c.1669G>A p.E557K (on ENST00000648592; = p.E523K on NM_182973.2) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV60225887; called by muse, mutect2, varscan2
- TNR | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV54867669; called by muse, mutect2, varscan2
- TRBV19 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs200808082; called by muse, mutect2, varscan2
- TRERF1 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV61667692; called by muse, mutect2, varscan2
- TRPV3 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100027898; called by mutect2, varscan2
- TRPV5 | c.488-1G>A p.X163_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV54690961; called by muse, mutect2, varscan2
- TSSK6 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99389146; called by muse, mutect2, varscan2
- TSSK6 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1228361348, COSV53063830; called by muse, mutect2, varscan2
- TTN | c.23002C>T p.P7668S (on ENST00000591111; = p.P6741S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | PolyPhen probably damaging (0.998); catalogued as COSV59906934; called by muse, mutect2, varscan2
- TTN | c.11207C>T p.P3736L (on ENST00000591111; = p.P3690L on NM_003319.4) | Missense Mutation (SNP) | VAF 15/170 reads (9%) | catalogued as COSV59906943; called by muse, mutect2
- TTN | c.9286G>A p.E3096K (on ENST00000591111; = p.E3050K on NM_003319.4) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | PolyPhen benign (0.359); catalogued as COSV59906961; called by muse, mutect2
- UGT2A1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as rs959283062, COSV54138372, COSV54140551; called by muse, mutect2, varscan2
- USP36 | c.2767C>T p.L923F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.814); catalogued as COSV61750303; called by muse, mutect2, varscan2
- USP38 | c.1132A>C p.T378P | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV61024925; called by muse, mutect2, varscan2
- ZFHX4 | c.8752C>T p.P2918S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.835); catalogued as rs1404887872, COSV50525534; called by muse, mutect2, varscan2
- ZFP42 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV58816555, COSV58819008; called by muse, mutect2
- ZFPM2 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV65872687; called by muse, mutect2, varscan2
- ZNF583 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV52401201; called by mutect2, varscan2
- ZNF585B | c.2290C>T p.H764Y | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs780185918, COSV57214665; called by muse, mutect2
- ZSCAN31 | c.673A>G p.K225E | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as COSV60180263; called by muse, mutect2, varscan2
- DST | c.2354_2356delinsTG p.T785Mfs*17 (on ENST00000361203 / NM_001374722.1; = p.T459Mfs*17 on NM_001723.6) | Frame Shift Del (DEL) | VAF 14/104 reads (13%) | called by pindel, varscan2*
- ACSM1 | c.756G>A p.R252= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV54638311; called by muse, mutect2
- AGO2 | c.873C>T p.H291= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs759640414, COSV55053880; called by muse, mutect2, varscan2
- ALX3 | c.546C>T p.A182= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100873891; called by muse, mutect2, varscan2
- ANKRD44 | c.405C>T p.V135= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as rs748551744, COSV56568446; called by muse, mutect2, varscan2
- APLP1 | c.546C>T p.S182= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV55707620; called by muse, mutect2, varscan2
- ARHGEF28 | c.4236C>T p.L1412= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs774585117, COSV55273703; called by muse, mutect2
- ARMC4 | c.1374G>A p.V458= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV53463661; called by muse, mutect2, varscan2
- ARPC2 | c.561A>G p.E187= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV55285743; called by muse, mutect2, varscan2
- ASPG | c.957C>T p.V319= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV71934218; called by muse, mutect2
- AUTS2 | c.2985G>A p.E995= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV61435318; called by muse, mutect2, varscan2
- BTRC | c.1584T>A p.I528= (on ENST00000370187 / NM_033637.4; = p.I492= on NM_003939.5) | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV64581471; called by muse, mutect2
- CCR5 | c.573G>A p.K191= | Silent (SNP) | VAF 36/203 reads (18%) | catalogued as COSV52750815, COSV52753277; called by muse, mutect2, varscan2
- CDH5 | c.1449C>T p.Y483= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV58520597; called by muse, mutect2, varscan2
- CFAP157 | c.651G>A p.T217= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1417544473, COSV58854794; called by muse, mutect2, varscan2
- CHGB | c.78G>A p.R26= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV66762132; called by muse, mutect2
- COBLL1 | c.702G>A p.Q234= (on ENST00000392717; = p.Q196= on NM_014900.5) | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV52078257; called by muse, mutect2, varscan2
- COL5A1 | c.2895C>T p.P965= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV65676731; called by muse, mutect2, varscan2
- CPN2 | c.33C>T p.S11= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV60472390; called by muse, mutect2, varscan2
- CYRIB | c.60C>T p.F20= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs981467615, COSV67833800; called by muse, mutect2, varscan2
- DNAH5 | c.11268G>A p.R3756= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV54226088; called by muse, mutect2, varscan2
- DUOX2 | c.2301C>T p.I767= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV66533410; called by muse, mutect2, varscan2
- EVPL | c.4461G>A p.Q1487= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as rs1268762342, COSV56911215; called by muse, mutect2, varscan2
- EXPH5 | c.4587C>T p.N1529= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV56209594; called by muse, mutect2, varscan2
- F2 | c.1524G>A p.K508= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV61316037; called by muse, mutect2
- FAM47C | c.2100C>T p.S700= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV63731201; called by muse, mutect2, varscan2
- FREM1 | c.3666C>T p.H1222= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs75281180, COSV66532115; called by muse, mutect2, varscan2
- FUS | c.846A>G p.S282= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV54220212; called by muse, mutect2
- HCAR1 | c.345C>T p.F115= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs756345373, COSV63678753; called by muse, mutect2, varscan2
- HCLS1 | c.750G>A p.R250= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV57528600; called by muse, mutect2, varscan2
- IDO2 | c.1224G>A p.*408= (on ENST00000389060; = p.*421= on NM_194294.2) | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV58430618; called by muse, mutect2
- IRAG1 | c.1332G>A p.Q444= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV70213283; called by muse, mutect2, varscan2
- ISL1 | c.525C>T p.H175= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV57936250; called by muse, mutect2, varscan2
- KDM2B | c.2358G>A p.P786= | Silent (SNP) | VAF 19/150 reads (13%) | catalogued as rs558946652, COSV65646042; called by muse, mutect2, varscan2
- LY86 | c.321C>T p.P107= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV57914313; called by muse, mutect2, varscan2
- MAGEC1 | c.1542C>T p.L514= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV53583174; called by muse, mutect2, varscan2
- MAGEC2 | c.795C>T p.F265= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs761420240, COSV55999921; called by muse, mutect2, varscan2
- MCF2L | c.516C>T p.F172= (on ENST00000375608; = p.F140= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV65054506; called by muse, mutect2
- MISP | c.1392G>A p.T464= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs554605500, COSV53122904; called by muse, mutect2, varscan2
- MMP2 | c.1905C>T p.A635= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as rs753643089, COSV50901173; called by muse, mutect2, varscan2
- MYOM2 | c.2778C>T p.I926= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs755880783, COSV50796332; called by muse, mutect2, varscan2
- OR1N1 | c.772C>T p.L258= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV59194957, COSV59196028; called by muse, varscan2
- OR2S2 | c.129T>C p.N43= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs777233315, COSV59531580; called by muse, mutect2, varscan2
- OSBPL8 | c.2628C>T p.L876= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV53890488; called by muse, mutect2, varscan2
- PAPPA | c.3430C>T p.L1144= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV60294150; called by muse, mutect2, varscan2
- PYGL | c.1191C>T p.L397= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99368813; called by muse, mutect2
- RASA3 | c.258C>T p.F86= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV61874913; called by muse, mutect2, varscan2
- SF3B2 | c.354C>T p.G118= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs1382484289, COSV100488550, COSV59430593; called by muse, mutect2, varscan2
- SH3TC1 | c.789C>T p.S263= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs200153598; called by muse, mutect2, varscan2
- SKIV2L | c.49C>T p.L17= | Silent (SNP) | VAF 77/430 reads (18%) | catalogued as COSV100952844, COSV64814826; called by muse, mutect2, varscan2
- SPEG | c.2904G>A p.L968= | Silent (SNP) | VAF 19/144 reads (13%) | catalogued as COSV56682277; called by muse, mutect2, varscan2
- SUMF2 | c.297G>A p.E99= (on ENST00000652303; = p.E80= on NM_015411.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV51919568; called by muse, mutect2, varscan2
- TAS2R41 | c.747C>T p.S249= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV68765994; called by muse, mutect2, varscan2
- TENM3 | c.4377C>T p.Y1459= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV69322371; called by muse, mutect2, varscan2
- TEX37 | c.357C>T p.A119= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV57557198; called by muse, mutect2, varscan2
- TIGD4 | c.891G>A p.K297= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as COSV58551079; called by muse, mutect2, varscan2
- TRBJ2-4 | c.33G>A p.G11= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- TRIP12 | c.4365T>A p.I1455= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs188045226, COSV52274464; called by muse, mutect2, varscan2
- TRPV3 | c.924G>A p.E308= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100027900; called by mutect2, varscan2
- ZNF536 | c.2856G>A p.V952= | Silent (SNP) | VAF 32/170 reads (19%) | catalogued as COSV62836807; called by muse, mutect2, varscan2
- ZNF875 | c.264G>A p.G88= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV60993240, COSV60994585; called by muse, mutect2
- DNAH8 | chr6:38723102 C>T | 5'Flank (SNP) | VAF 14/74 reads (19%) | catalogued as COSV59427200; called by muse, mutect2, varscan2
- TLE4 | c.391-2745G>A | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
